Somatic mutation profile of tumor specimen MMRF_2400_1_BM_CD138pos (aliquot MMRF_2400_1_BM_CD138pos_T1_KHS5U_L11091) from MMRF case MMRF_2400, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.1 years (24,888 days).
Specimen MMRF_2400_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbe3125f-dae9-4061-b43d-1b8dd5581959.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2400_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2400_1_PB_Whole_C3_KHS5U_L11092; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8634312b-c2bf-42fe-8c32-5f216daa1d91

The open-access MAF lists 76 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, 3'UTR 21, Silent 7, Intron 6, Nonsense Mutation 5, RNA 4, 5'Flank 3, Frame Shift Del 2, 5'UTR 1, Frame Shift Ins 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 35/180 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DNASE2 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as CD100619; called by muse, mutect2, varscan2
- DSCAML1 | c.400C>T p.R134W (on ENST00000321322; = p.R74W on NM_020693.4) | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339097046, COSV58383358; called by muse, varscan2
- FCHSD1 | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as rs770759490, COSV71300498; called by muse, mutect2, varscan2
- IGHA1 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.588); catalogued as rs768083331; called by muse, mutect2, varscan2
- IGHV2-70 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 61/62 reads (98%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs369066675; called by muse, mutect2, varscan2
- IGLV3-1 | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 67/71 reads (94%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as rs750211358; called by muse, varscan2
- IGLV3-1 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 46/48 reads (96%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs61731683; called by muse, mutect2, varscan2
- IGLV5-45 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.176); catalogued as rs766982559; called by muse, varscan2
- IPO4 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs767082261; called by muse, mutect2, varscan2
- LHCGR | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 112/273 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99684306; called by muse, mutect2, varscan2
- MUC2 | c.3961G>A p.G1321S | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1222595863; called by muse, mutect2, varscan2
- NHSL1 | c.3974C>T p.P1325L | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs907532565; called by muse, mutect2, varscan2
- RAB26 | c.594G>A p.E198= | Splice Region (SNP) | VAF 29/108 reads (27%) | catalogued as rs756810720; called by muse, mutect2, varscan2
- TNFRSF11A | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.223); catalogued as COSV54023182; called by muse, mutect2, varscan2
- TOP2B | c.4625G>A p.R1542Q (on ENST00000264331 / NM_001330700.2; = p.R1537Q on NM_001068.3) | Missense Mutation (SNP) | VAF 136/430 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.406); catalogued as rs749334778, COSV51969679; called by muse, mutect2, varscan2
- BCAS3 | c.689T>C p.M230T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF4G1 | c.1195C>T p.Q399* (on ENST00000346169 / NM_198241.3; = p.Q203* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 131/410 reads (32%) | called by muse, mutect2, varscan2
- EPHA3 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 40/127 reads (31%) | called by muse, mutect2, varscan2
- FAM81A | c.635A>C p.Q212P | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- GDI1 | c.13T>A p.Y5N | Missense Mutation (SNP) | VAF 145/145 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GPR176 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPRIN3 | c.1409A>C p.Q470P | Missense Mutation (SNP) | VAF 78/151 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- IGLV7-46 | c.291G>C p.L97F | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- MAGEA12 | c.471C>A p.Y157* | Nonsense Mutation (SNP) | VAF 105/279 reads (38%) | called by muse, mutect2, varscan2
- MDN1 | c.7400G>C p.R2467T | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.42); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MIDEAS | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2
- MOAP1 | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- NWD2 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PHF12 | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- RBM27 | c.1180del p.R394Vfs*125 | Frame Shift Del (DEL) | VAF 39/395 reads (10%) | called by mutect2, pindel, varscan2
- SLC11A1 | c.597dup p.G200Wfs*14 | Frame Shift Ins (INS) | VAF 26/64 reads (41%) | called by mutect2, varscan2
- ZNF236 | c.5136del p.S1713Lfs*2 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | called by mutect2, pindel, varscan2
- ADGRB2 | c.918G>A p.Q306= | Silent (SNP) | VAF 34/63 reads (54%) | called by muse, mutect2, varscan2
- AL772284.1 | c.561C>T p.G187= | Silent (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
- CDC42BPG | c.2433C>T p.S811= | Silent (SNP) | VAF 48/121 reads (40%) | catalogued as rs866598760; called by muse, mutect2, varscan2
- DEGS2 | c.522G>A p.P174= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs536908308; called by muse, mutect2, varscan2
- IGLV5-45 | c.231G>A p.K77= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as rs370576104; called by muse, varscan2
- NEUROD1 | c.240G>A p.K80= | Silent (SNP) | VAF 60/130 reads (46%) | catalogued as rs769477247, COSV54549905; called by muse, mutect2, varscan2
- SLC28A1 | c.756G>T p.V252= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV54482433; called by muse, mutect2, varscan2
- ACER3 | c.*584G>T | 3'UTR (SNP) | VAF 51/149 reads (34%) | catalogued as rs1156816877; called by muse, mutect2, varscan2
- ACTR3 | c.*4738G>A | 3'UTR (SNP) | VAF 29/57 reads (51%) | catalogued as rs977589631; called by muse, mutect2, varscan2
- ALG13 | c.*97A>G | 3'UTR (SNP) | VAF 40/41 reads (98%) | called by muse, mutect2, varscan2
- ANK2 | c.*468C>A | 3'UTR (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- BAIAP2L2 | c.*63G>A | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- CDC73 | c.*1264T>C | 3'UTR (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- CRADD | c.*243G>T | 3'UTR (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- FUT9 | c.*310T>C | 3'UTR (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- GCSAML | c.*2288C>T | 3'UTR (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- HEXD | c.982+101G>A | Intron (SNP) | VAF 21/88 reads (24%) | catalogued as rs1450221121; called by muse, mutect2, varscan2
- HNF1B | c.1045+172G>A | Intron (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2
- IGLV1-41 | n.126C>G | RNA (SNP) | VAF 32/57 reads (56%) | called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.*383A>G | 3'UTR (SNP) | VAF 27/100 reads (27%) | catalogued as COSV61849351; called by muse, mutect2, varscan2
- KRT18P55 | n.565T>C | RNA (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- LAIR2 | chr19:54498058 C>G | 5'Flank (SNP) | VAF 44/404 reads (11%) | catalogued as rs566254566; called by muse, mutect2
- LATS2 | c.*1654C>T | 3'UTR (SNP) | VAF 71/160 reads (44%) | catalogued as rs192739453; called by muse, mutect2, varscan2
- LINC01620 | n.327C>T | RNA (SNP) | VAF 170/314 reads (54%) | catalogued as rs1336921129; called by muse, mutect2, varscan2
- MLIP | c.1114-13649T>G | Intron (SNP) | VAF 38/85 reads (45%) | called by muse, mutect2, varscan2
- NPEPPS | c.*237A>G | 3'UTR (SNP) | VAF 23/39 reads (59%) | called by muse, mutect2, varscan2
- OR51F5P | n.378T>C | RNA (SNP) | VAF 24/216 reads (11%) | called by muse, mutect2, varscan2
- PARP11 | chr12:3807074 C>T | 3'Flank (SNP) | VAF 27/74 reads (36%) | catalogued as rs1312557725; called by muse, mutect2, varscan2
- PHC3 | c.378+1331del | Intron (DEL) | VAF 8/74 reads (11%) | catalogued as rs200687062; called by pindel, varscan2
- PLCL2 | c.*212G>A | 3'UTR (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- PPP1R3A | c.*355del | 3'UTR (DEL) | VAF 14/40 reads (35%) | catalogued as rs914567975; called by mutect2, varscan2
- PPP2R2B | c.*343G>C | 3'UTR (SNP) | VAF 50/201 reads (25%) | called by muse, mutect2, varscan2
- PTPRG | c.*517G>A | 3'UTR (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.-85G>T | 5'UTR (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2, varscan2
- RHOBTB3 | chr5:95731288 C>A | 5'Flank (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- SIKE1 | c.408+19A>G | Intron (SNP) | VAF 47/49 reads (96%) | called by muse, mutect2, varscan2
- SYT11 | c.*1461del | 3'UTR (DEL) | VAF 28/54 reads (52%) | called by mutect2, varscan2
- TAB1 | c.*550C>G | 3'UTR (SNP) | VAF 27/124 reads (22%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.*3660G>A | 3'UTR (SNP) | VAF 27/78 reads (35%) | catalogued as rs1486016965, COSV101467769; called by muse, mutect2, varscan2
- U2SURP | c.1275-1012C>T | Intron (SNP) | VAF 48/126 reads (38%) | called by muse, mutect2, varscan2
- UBE3B | chr12:109477484 G>A | 5'Flank (SNP) | VAF 50/101 reads (50%) | called by muse, mutect2, varscan2
- ZNF197 | c.*597C>T | 3'UTR (SNP) | VAF 5/15 reads (33%) | catalogued as rs1336874101; called by muse, mutect2, varscan2
- ZNF568 | c.*1330T>A | 3'UTR (SNP) | VAF 42/109 reads (39%) | called by muse, mutect2, varscan2
